Somatic mutation profile of tumor specimen ALCH-B3EP-TTP1-A (aliquot ALCH-B3EP-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3EP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.8 years (22,567 days).
Specimen ALCH-B3EP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61d26240-4604-4e4d-b112-dcf443c10faf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3EP-NB1-A (Blood Derived Normal), aliquot ALCH-B3EP-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/523aa4c5-77ab-4dd0-9e79-c145172ac59d

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 6, Nonsense Mutation 4, Intron 3, 5'UTR 2, RNA 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 33/290 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2438C>T p.S813L | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795105, COSV60807773; ClinVar: likely pathogenic; called by muse, mutect2
- AMPD1 | c.1714C>A p.P572T | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM148993, COSV62415955; called by muse, mutect2, varscan2
- CXXC5 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV56795951; called by muse, mutect2, varscan2
- EXOC2 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479517377; called by muse, mutect2
- FRYL | c.8455G>A p.D2819N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99976341; called by muse, mutect2, varscan2
- GAS1 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs1032793536; called by muse, mutect2, varscan2
- GBX2 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs763316927; called by muse, mutect2, varscan2
- GRIA3 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV52049568; called by muse, mutect2
- HBD | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 43/368 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs34802738; ClinVar: other; called by muse, mutect2, varscan2
- ICA1 | c.12C>A p.H4Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs779789569; called by muse, mutect2, varscan2
- LRRK2 | c.4642A>G p.I1548V | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.282); catalogued as COSV54143072; called by muse, mutect2, varscan2
- NRG2 | c.897C>G p.N299K | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.208); catalogued as COSV56839282; called by muse, mutect2, varscan2
- PHF1 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); catalogued as rs1187220918; called by muse, mutect2
- RFPL1 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs759032513; called by muse, mutect2, varscan2
- SLC35A4 | c.953G>T p.R318L | Missense Mutation (SNP) | VAF 27/288 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV100021034; called by muse, mutect2
- CACNA1B | c.2069T>A p.I690N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DAAM2 | c.2582C>T p.S861L | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); called by muse, mutect2
- DIPK2B | c.696G>A p.W232* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2
- GFOD1 | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2
- HCN3 | c.1186A>G p.M396V | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- HIPK3 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 20/172 reads (12%) | called by muse, mutect2, varscan2
- IGFBP1 | c.640A>T p.S214C | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- ITGAL | c.2963G>C p.W988S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGBL1 | c.265T>A p.C89S | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KLC3 | c.856dup p.E286Gfs*43 | Frame Shift Ins (INS) | VAF 10/86 reads (12%) | called by mutect2, varscan2
- NHSL2 | c.904C>A p.Q302K (on ENST00000510661; = p.Q668K on NM_001013627.2) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCB1 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 11/172 reads (6%) | called by muse, mutect2
- RPS3 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2
- SLC6A11 | c.1722G>A p.W574* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2
- UGGT2 | c.4274A>G p.N1425S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WDR33 | c.2389G>C p.A797P | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.039); called by muse, mutect2
- ZDHHC14 | c.1022C>G p.S341C | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.156); called by muse, mutect2
- EVX2 | c.315T>C p.Y105= | Silent (SNP) | VAF 33/271 reads (12%) | called by muse, mutect2, varscan2
- KMT2C | c.10314C>G p.G3438= | Silent (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.1872C>A p.I624= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- SNTB1 | c.1200G>A p.T400= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs377444423; called by muse, mutect2, varscan2
- TACC1 | c.2208C>T p.H736= | Silent (SNP) | VAF 18/152 reads (12%) | catalogued as rs776268614; called by muse, mutect2, varscan2
- TUBA4A | c.1185C>T p.F395= | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as rs562895831; called by muse, mutect2, varscan2
- ACOT9 | c.-38G>C | 5'UTR (SNP) | VAF 6/54 reads (11%) | catalogued as rs1184781069; called by muse, mutect2, varscan2
- APOBEC3F | c.172-771C>T | Intron (SNP) | VAF 19/119 reads (16%) | catalogued as COSV100415190; called by muse, mutect2, varscan2
- CFAP299 | c.-4C>G | 5'UTR (SNP) | VAF 31/291 reads (11%) | catalogued as rs748478258; called by muse, mutect2, varscan2
- EARS2 | c.139+244C>T | Intron (SNP) | VAF 17/187 reads (9%) | catalogued as rs1381417021; called by muse, mutect2
- PLEKHM1P1 | n.1904G>A | RNA (SNP) | VAF 41/369 reads (11%) | called by muse, mutect2, varscan2
- RANBP17 | chr5:170861984 C>T | 5'Flank (SNP) | VAF 8/58 reads (14%) | catalogued as rs1423687321; called by muse, mutect2, varscan2
- SERPINA13P | n.587G>T | RNA (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- WDPCP | c.1748+8942G>T | Intron (SNP) | VAF 29/236 reads (12%) | catalogued as rs935216641; called by muse, mutect2, varscan2
